Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5718, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5718-01A (Primary Tumor).

TCGA-CG-5718

Diagnosis:

Total gastrectomy specimen with a partially exophytic, flat, ulcerated gastric carcinoma of maximum diameter 4 cm on the lesser curvature side in the corpus portion, of the histological type of a moderately differentiated adenocarcinoma (gastric carcinoma of the intestinal type). Invasive tumor dissemination within all gastric wall layers as far as the subserosal and perigastric fatty tissue level with lymphatic and perineural tumor extensions.

Antral mucosa with mild to moderate, non-florid chronic gastritis and foveolar hyperplasia, and corpus mucosa with moderately florid chronic gastritis, slight foveolar hyperplasia and focal intestinal metaplasia with evidence of *Helicobacter pylori*.

Oral and aboral resection margin tumor-free.

Three of 36 perigastric lymph nodes with metastases from the gastric carcinoma.

Therefore tumor stage pT2b (associated with the histological findings) pN1
(3/39)

Source: NCI Genomic Data Commons file 9c6a1833-bed6-4c41-8a19-25338b48001e (TCGA-CG-5718.76E0013B-BD9B-4B74-BB35-F3AA36A95A56.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).